Surgical pathology report (de-identified scan), TCGA case TCGA-90-A59Q, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-90-A59Q-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3

Carcinoma, Squamous Cell, NOS
8070/3

Site: (R) Lung, upper lobe C34.1
9/5 1/2/13

Operative Procedure:

Right upper lobectomy

Pre-Operative Diagnosis:

See below

Post-Operative Diagnosis:

See below

Specimen Received:

A: Right upper and middle lobe

B: Level 7

C: Level 2

D: Level 4

E: Bronchial margin (FS)

Final Pathologic Diagnosis:

A. Lung, right upper and middle lobe, lobectomy: Poorly differentiated
squamous cell carcinoma

Specimen: Lung: Upper and middle lobes

Procedure: Bilobectomy

Specimen laterality: right

Tumor site: upper lobe

Specimen integrity: intact

Tumor size: 4.9 cm (greatest dimension)

Tumor focality: Unifocal

Tumor histologic type: Squamous cell carcinoma

Tumor grade: poorly differentiated

Visceral pleura invasion: negative

Tumor extension: confined to the lung

Margins:

Bronchial margin: Uninvolved by invasive carcinoma

Squamous cell carcinoma in situ (CIS) not identified at
bronchial margin]

Vascular margin: Uninvolved by invasive carcinoma;

Parenchymal margin: Not applicable

Parietal pleural margin: Not applicable

Chest wall margin: Not applicable

Other attached tissue margin: Not applicable

If all margins uninvolved by invasive carcinoma:

Distance of invasive carcinoma from closest margin: can not be
determined

Specify margin: Not applicable

Treatment effect: Not applicable

Lymph-vascular invasion: indeterminate

[page 2 of 3]
Pathologic Staging (pTNM):

TNM Descriptors: none known

Primary tumor (pT): pT 2a

Regional lymph nodes (pN): pN 1

Number examined: 15

Number involved: 1

If lymph node(s) involved, specify involved nodal station(s):

11-12 r

Distant metastasis (pM): pM not known

Additional pathologic findings: Respiratory bronchiolitis

B. Lymph node, level 7, excision:

No significant pathologic change (1)

C. Lymph node, level 2, excision:

No significant pathologic change (1)

D. Lymph node, level 4, excision:

No significant pathologic change (1)

E. Bronchus, right upper lobe margin, excision:

No significant pathologic change.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Intraoperative Consult Diagnosis:

FSE: Bronchial margin:

Negative for carcinoma.

F/S TAT: 16 mins.

Gross Description:

Received are five containers, all labeled with the patient's name,

Part A is received in formalin additionally labeled "right upper and middle lobe" and consists of an 18.9 x 13 x 5.7 cm lobe of lung. The pleura is purple-tan to pink, smooth and glistening and has been previously inked black and incised. No parenchymal staple lines are present. The exposed hilar edge is inked blue. Sectioning reveals a mass that is tan to white with ill defined borders, having dimensions of 4.9 x 3.9 x 2.8 cm. This mass comes to within 1.7 cm of the pleural edge and 1.5 cm of the inked exposed hilar edge. The mass appears to involve the bronchus. The uninvolved parenchyma is red to pink.

Representative sections are submitted as follows:

A1 vascular margin;

A2 mass to bronchus;

A3 mass to pleura;

A4-5 representative sections of mass;

[page 3 of 3]
- A6 uninvolved parenchyma;
- A7 one lymph node sectioned;
- A8 four probable lymph nodes;
- A9 one probable lymph node trisected;
- A10 four probable lymph nodes;
- A11 one probable lymph node sectioned;
- A12 one probable lymph node sectioned.

Part B is received in formalin additionally labeled "level 7" and consists of a single portion of pink-tan irregular soft tissue with dimensions of 2.4 x 1.9 x 1.1 cm. The specimen is sectioned and entirely submitted in cassettes 1 and 2.

Part C is received in formalin and additionally labeled "level 2" and consists of a single portion of pink-tan irregular soft tissue with dimensions of 2.1 x 1.5 x 1.1 cm. The specimen is bisected and entirely submitted in cassette C1.

Part D is received in formalin and additionally labeled "level 4" and consists of a single portion of pink-tan to brown irregular soft tissue with dimensions of 3.4 x 2.4 x 1.5 cm. The specimen is sectioned and entirely submitted in cassettes D1-D4.

Part E is received fresh for frozen section and additionally labeled "bronchial margin" and consists of a pink-tan portion of soft tissue with diameter of 0.7 cm. Residual tissue from frozen section is submitted in cassette E1.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings. Special stains (IMPOX) were performed in order to further characterize the tumor. The tumor stains focally for p63 and CK5/6. It is negative for Napain and TTF-1. Controls stain appropriately. The findings support the interpretation.

END OF REPORT

Taken:

Gender: F

Criteria	12/14/12	Yes	No

Source: NCI Genomic Data Commons file 27a8011c-fedc-406b-941c-a012de460e49 (TCGA-90-A59Q.EB15D79B-A4EF-4393-8759-E623A7282E0C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).